Surgical pathology report (de-identified scan), TCGA case TCGA-BB-7862, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-7862-01A (Primary Tumor).

[page 1 of 5]
INTERPRETATION AND DIAGNOSIS:

- 1) TONGUE, DEEP MARGIN (EXCISION): NEGATIVE FOR TUMOR.
- 2) TONGUE MUCOSA, SUPERFICIAL MARGIN (EXCISION): NEGATIVE FOR TUMOR.
- 3) NECK, LEFT LEVEL 2 (DISSECTION): METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING ONE (1) OF SIX (6) LYMPH NODES.
- 4) NECK LEFT LEVEL 3 AND 4 (DISSECTION):
- LEVEL 3: SEVEN (7) LYMPH NODES, NEGATIVE FOR TUMOR.
- LEVEL 4: EIGHT (8) LYMPH NODES, NEGATIVE FOR TUMOR.
- 5) NECK, RIGHT LEVELS 2-4 (DISSECTION):
- LEVEL 2: METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING ONE (1) OF SEVEN (7) LYMPH NODES.
- LEVEL 3: NINE (9) LYMPH NODES, NEGATIVE FOR TUMOR.
- LEVEL 4: ELEVEN (11) LYMPH NODES, NEGATIVE FOR TUMOR.
- 6) LARYNX (TOTAL LARYNGECTOMY):

SPECIMEN:
Laryngectomy, neck dissection

TUMOR SITE:
Supraglottis

HISTOLOGIC TYPE:
Squamous cell carcinoma

TUMOR SIZE:
Greatest dimension 3.2 cm

HISTOLOGIC GRADE:
G3: Moderately to poorly differentiated

LYMPH NODES:
Metastatic carcinoma in 2 of 48 lymph nodes

EXTRANODAL EXTENSION:
Not identified

EXTENT OF INVASION
PRIMARY TUMOR:

FINAL DOCUMENT

[page 2 of 5]
pT3: Tumor invades preepiglottis.

REGIONAL LYMPH NODES:

pN2: Metastasis in single or multiple lymph nodes, none larger than 6 cm

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins are uninvolved. Distance of invasive carcinoma from nearest margin: 1 mm

VENOUS/LYMPHATIC INVASION:

Present

PERINEURAL INVASION:

Not identified

[REDACTED]

*Electronic signature by which I attest that the above diagnosis is based upon my personal examination of the slides (and / or other material indicated in the diagnosis), and that I have reviewed and approved this report.

Clinical History:

GROSS DESCRIPTION

PART #1: FS: TONGUE DEEP MARGIN [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists / [REDACTED]

FS: TONGUE DEEP MARGIN: NEGATIVE FOR TUMOR.

Dictated by [REDACTED]

The specimen is received fresh for frozen section labeled with the patient's name, [REDACTED] and designated 'tongue deep margin'. The specimen consists of one (1) fragment of red tan soft tissue, measuring 1.1 x 0.4 x 0.3 cm. The specimen is entirely submitted for frozen.

SUMMARY OF SECTIONS:

1 - FSC - 1 (TONGUE DEEP MARGIN)

1 - TOTAL - 1

PART #2: FS: TONGUE MUCOSA SUPERFICIAL MARGIN [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists / [REDACTED]

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 3 of 5]
FS: TONGUE MUCOSA SUPERFICIAL MARGIN: NEGATIVE FOR TUMOR.

Dictated by [REDACTED]

The specimen is received fresh for frozen section labeled with the patient's name, [REDACTED] and designated 'tongue mucosa superficial margin'. The specimen consists of one (1) fragment of red tan soft tissue measuring 2.0 x 0.3 x 0.2 cm. The specimen is bisected and entirely submitted for frozen.

SUMMARY OF SECTIONS:

1 - FSC - 2 (TONGUE MUCOSA SUPERFICIAL MARGIN)
1 -TOTAL - 2

PART #3: LEFT NECK LEVEL 2 [REDACTED]

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh labeled with the patient's name, [REDACTED] and designated 'left neck level II'. The specimen consists of red pink fibrofatty soft tissue measuring 5.7 x 2.3 x 0.7 cm. Blunt dissection reveals two (2) candidate lymph nodes measuring 0.7 cm and 0.4 cm in diameter. The nodes along with the remaining soft tissue are submitted in entirety.

SUMMARY OF SECTIONS:

1 - A - 2 (TWO CANDIDATE LYMPH NODES)
1 - B - 2 (REMAINING SOFT TISSUE)
1 - C - 1 (REMAINING SOFT TISSUE)
2 - D-E - 2 EA. (REMAINING SOFT TISSUE)
1 - F - 1 (REMAINING SOFT TISSUE)
6 - TOTAL - 10

PART #4: LEFT NECK LEVEL 3 AND 4 [REDACTED]

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh labeled with the patient's name, [REDACTED] and designated 'left neck levels 3 and 4'. It consists of red, pink soft tissue, measuring 6.5 x 2.5 x 1.6 cm. Staples are used to designated the levels 3 and 4. The specimen is separated and each individual level bluntly dissected to reveal three candidate lymph nodes in level 3 ranging in size from 0.5 to 0.3 cm and the two (2) candidate lymph nodes in level 4 measuring 0.5 and 0.3 cm. The lymph nodes and soft tissue are submitted in its entirety.

SUMMARY OF SECTIONS:

1 - A - 2 (THREE LYMPH NODES, LEVEL 3)
2 - B-C - 1 EA. (SOFT TISSUE)
1 - D - 1 (TWO LYMPH NODES, LEVEL 4)
3 -E-G - 1 EA. (SOFT TISSUE LEVEL 4)
7 -TOTAL - 9

PART #5: RIGHT NECK LEVELS 2-4 [REDACTED]

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 4 of 5]
Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh labeled with the patient's name, [REDACTED] and designated 'right neck level 2-4'. It consists of red pink fibrous soft tissue measuring 15 x 2.5 x 1.1 cm. Levels 2-4 are designated with staples and arbitrarily separated. Blunt dissection reveals two (2) lymph nodes in level 2, and one (1) lymph node in level 3, and five candidate lymph nodes in level 4. Those along with soft remaining tissue are submitted. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS:

2 - A-B - 2 EA. (LYMPH NODE BISECTED LEVEL II)
3 - C-E - M (SOFT TISSUE LEVEL 2)
1 - F - 1 (LYMPH NODE, LEVEL 3)
3 - G-I - 1 EA. (SOFT TISSUE LEVEL)
1 - J - 5 (FIVE LYMPH NODE LEVEL 4)
1 - K - M (SOFT TISSUE LEVEL 4)
2 - L-M - 1 EA. (SOFT TISSUE, LEVEL 4)
13 -TOTAL - M

PART #6: TOTAL LARYNGECTOMY [REDACTED]

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh labeled with the patient's name [REDACTED] and designated 'total laryngectomy'. The specimen consists of a total laryngectomy measuring 10.5 x 8.5 x 6 cm, including a portion of the hyoid bone measuring 7.5 x 0.3 x 0.3 cm, the larynx from epiglottis to subglottis and three (3) tracheal rings. There is an irregular, firm tan white mass with ulceration measuring 3.1 x 3.2 x 1.6 cm located in the supraglottis and grossly involving the false cord and possibly the true cord. The mass is less than 0.2 cm from the closest mucosal margin (left aryepiglottic fold) and 3.6 cm from the distal tracheal margin. The mass invades into the lamina propria, grossly very close (less than 0.1 to 0.2 cm of the inked margin. The mass does not appear to grossly invade into the serially sectioned red brown strap muscles (which are unremarkable), or into the thyroid cartilage. Along with standard sections, a midline section is submitted for decalcification. Approximately 5% of the total specimen is submitted.

SUMMARY OF SECTIONS:

1 - A - 1 (EPIGLOTTIS)
1 - B - 1 (RIGHT ARYEPIGLOTTIC FOLDS)
1 - C - 1 (LEFT ARYEPIGLOTTIC FOLD)
1 - D - 1 (TRACHEAL RING)
1 - E - 1 (RIGHT ARYTENOID)
1 - F - 1 (LEFT ARYTENOID)
1 - G - 1 (MIDLINE TUMOR)
1 - H - 1 (RIGHT INFERIOR TO TRUE VOCAL CORD)
1 - I - 1 (RIGHT SUPERIOR TO FALSE VOCAL CORD)
1 - J - 1 (RIGHT THROUGH FALSE AND TRUE VOCAL CORDS)
1 - K - 1 (LEFT INFERIOR TO TRUE VOCAL CORD)
1 - L - 1 (LEFT SUPERIOR TO FALSE VOCAL CORD)
1 - M - 1 (LEFT THROUGH FALSE AND TRUE VOCAL CORDS)
1 - N - 1 (RIGHT SOFT TISSUE CLOSEST TO TUMOR)

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 5 of 5]
1 - O - 1 (LEFT SOFT TISSUE CLOSEST TO TUMOR)
1 - P - 1 (RIGHT CARTILAGE)
1 - Q - 1 (LEFT CARTILAGE)
1 - R - 1 (RIGHT STRAP MUSCLE)
1 - S - 1 (LEFT STRAP MUSCLE)
19 -TOTAL - 19

Other Surgical Pathology Specimens known to the computer:

=====

(End of Report)

Note: This note provides information pertaining only to a specific event. A more detailed medical history is available in the Medical Record.

FINAL DOCUMENT

Source: NCI Genomic Data Commons file 7756d86e-08cd-4ce6-83ed-55cce2a18875 (TCGA-BB-7862.D66F9387-2FBB-45C4-A571-37D7B8BBB90E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).